Somatic mutation profile of tumor specimen ALCH-B3GE-TTP1-A (aliquot ALCH-B3GE-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3GE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,175 days).
Specimen ALCH-B3GE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d9d1915-6752-4fcf-a81b-7aabe5369451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GE-NB1-A (Blood Derived Normal), aliquot ALCH-B3GE-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bed5101-f46f-43dc-8464-74b40077f962

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Intron 4, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 140/376 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs727504256, COSV51767260, COSV51795875; ClinVar: drug response; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 143/427 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 81/286 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGTR1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV62560471; called by muse, mutect2, varscan2
- BCAN | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs148943492; called by muse, mutect2, varscan2
- CEP192 | c.6512C>T p.A2171V | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759227169, COSV100381530; called by muse, mutect2, varscan2
- KCNT1 | c.3068G>A p.R1023Q (on ENST00000488444; = p.R1042Q on NM_020822.3) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763578184; ClinVar: uncertain significance; called by muse, mutect2
- LRRC8E | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs766197115; called by muse, mutect2, varscan2
- NPR2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV100709276; called by muse, mutect2, varscan2
- OR51E1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs754916734; called by muse, mutect2, varscan2
- TMPRSS13 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs760074587; called by muse, mutect2, varscan2
- TRIM50 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs782227335; called by muse, mutect2
- WDR62 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 95/393 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs200939815; called by muse, mutect2, varscan2
- C1orf167 | c.2270C>A p.A757D | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CNTN5 | c.228T>A p.Y76* | Nonsense Mutation (SNP) | VAF 74/592 reads (13%) | called by muse, mutect2, varscan2
- COL6A5 | c.3272T>G p.V1091G | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GLMN | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- GPT | c.1363A>T p.S455C | Missense Mutation (SNP) | VAF 123/326 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- GRIA1 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM5 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LIPT2 | c.262_270del p.L88_T90del | In Frame Del (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- MYOM1 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN3 | c.317C>G p.P106R (on ENST00000557594 / NM_001272020.2; = p.P738R on NM_004796.6) | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROGDI | c.433-3C>A | Splice Region (SNP) | VAF 54/181 reads (30%) | called by muse, mutect2, varscan2
- SPPL2A | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0.345); called by muse, mutect2
- TSPAN17 | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- USP9Y | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- VILL | c.2423A>G p.D808G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2
- HIVEP1 | c.1620T>C p.N540= | Silent (SNP) | VAF 60/228 reads (26%) | catalogued as COSV65104143; called by muse, mutect2, varscan2
- MOV10 | c.420T>C p.L140= | Silent (SNP) | VAF 75/349 reads (21%) | called by muse, mutect2, varscan2
- MUC5B | c.17178G>A p.L5726= | Silent (SNP) | VAF 76/348 reads (22%) | called by muse, mutect2, varscan2
- RIPK4 | c.414A>G p.P138= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs769421962; called by muse, mutect2
- USP9Y | c.150G>A p.E50= | Silent (SNP) | VAF 69/168 reads (41%) | called by muse, mutect2, varscan2
- CATSPERG | c.-15+360G>A | Intron (SNP) | VAF 20/70 reads (29%) | catalogued as rs1185547162; called by muse, mutect2, varscan2
- ECH1 | c.52+17C>T | Intron (SNP) | VAF 43/183 reads (23%) | catalogued as rs1422612748; called by muse, mutect2, varscan2
- NPDC1 | c.113-39G>A | Intron (SNP) | VAF 20/111 reads (18%) | catalogued as rs764637718; called by muse, mutect2, varscan2
- PCDH10 | c.2631+19G>A | Intron (SNP) | VAF 23/85 reads (27%) | catalogued as COSV52094850; called by muse, varscan2
